Somatic mutation profile of tumor specimen TCGA-61-1740-01A (aliquot TCGA-61-1740-01A-01W-0639-09) from TCGA case TCGA-61-1740, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,169 days).
Specimen TCGA-61-1740-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0ec2aa4-6940-49bc-b8a6-ee2b02baeb80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1740-11A (Solid Tissue Normal), aliquot TCGA-61-1740-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db3393db-a672-474c-b460-9321d06d7b34

The open-access MAF lists 226 somatic variants for this specimen: 168 protein-altering or splice-affecting, 51 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 51, Splice Site 9, Frame Shift Del 7, Nonsense Mutation 7, In Frame Del 6, Intron 3, RNA 2, Splice Region 1, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786204931, CM020755, COSV64290794, COSV64294365; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 168/397 reads (42%) | catalogued as CM138700, COSV57050405; called by muse, mutect2, varscan2
- AC092143.1 | c.2175C>A p.F725L | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV59247224; called by muse, mutect2, varscan2
- ACP7 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs550310336, COSV58698433; called by muse, mutect2, varscan2
- ACVR1 | c.511A>T p.I171F | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.411); catalogued as COSV55116978; called by muse, mutect2, varscan2
- ADAMTS6 | c.1985A>C p.Y662S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.191); catalogued as COSV66857508; called by muse, mutect2, varscan2
- ADCK1 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53078985; called by muse, mutect2, varscan2
- ADCY2 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57861775; called by muse, mutect2, varscan2
- ADGRF5 | c.3676C>G p.P1226A | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51930685; called by muse, mutect2, varscan2
- ADGRG2 | c.415-1G>C p.X139_splice (on ENST00000379869 / NM_001079858.3; = p.X136_splice on NM_005756.4) | Splice Site (SNP) | VAF 15/357 reads (4%) | catalogued as COSV100491931, COSV61337428; called by muse, mutect2
- AFF3 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57843453; called by muse, mutect2, varscan2
- AIM2 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 131/666 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63698548; called by muse, mutect2, varscan2
- ALK | c.3515+1G>A p.X1172_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as COSV66560042; called by muse, mutect2, varscan2
- ALKBH8 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52833657; called by muse, mutect2, varscan2
- AOC1 | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV62867265; called by muse, mutect2, varscan2
- ARHGAP39 | c.2704C>T p.R902C (on ENST00000276826 / NM_001308208.2; = p.R933C on NM_025251.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs1378531747, COSV52766881; called by muse, mutect2
- ARHGEF10 | c.3290C>A p.A1097D (on ENST00000398564; = p.A1072D on NM_014629.4) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV50643277; called by muse, mutect2, varscan2
- ATP1A4 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 148/431 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs773940781, COSV63625715; called by muse, mutect2, varscan2
- BAG1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV56302722; called by muse, mutect2, varscan2
- CACNG2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55632776; called by muse, mutect2, varscan2
- CARD6 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 127/852 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54564644; called by muse, mutect2, varscan2
- CASK | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV59362849, COSV59362897; called by muse, mutect2, varscan2
- CCR3 | c.880T>G p.C294G | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62461925; called by muse, mutect2, varscan2
- CDC5L | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.178); catalogued as COSV65175493; called by muse, mutect2, varscan2
- CENPF | c.2185A>T p.T729S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV65273153; called by muse, mutect2, varscan2
- CEP152 | c.1696C>A p.Q566K | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100358560; called by muse, mutect2
- CFAP251 | c.939G>C p.W313C | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56610160, COSV99995778; called by muse, mutect2
- CLASRP | c.1721C>G p.P574R | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55514741; called by muse, mutect2, varscan2
- CLEC17A | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV60426994; called by muse, mutect2, varscan2
- CNTN5 | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54288522; called by muse, mutect2, varscan2
- CRAMP1 | c.2527C>A p.H843N | Missense Mutation (SNP) | VAF 10/338 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99245672; called by muse, mutect2
- CTNNA3 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 170/480 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV65559131, COSV65583038; called by muse, mutect2, varscan2
- CWC15 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99688442; called by muse, mutect2
- CXCR2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV59279898; called by muse, mutect2, varscan2
- DDX11 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299047; called by muse, mutect2
- DENND2A | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs573861843, COSV52054083; called by muse, mutect2
- DMXL1 | c.5387G>C p.R1796T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100223413; called by muse, mutect2
- DNAH7 | c.9080G>A p.C3027Y | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1184824901, COSV56754803; called by muse, mutect2, varscan2
- DOCK5 | c.3985G>T p.E1329* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV52408770, COSV99376196; called by muse, mutect2, varscan2
- DOCK5 | c.3986A>T p.E1329V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99376199; called by muse, mutect2, varscan2
- EBAG9 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 56/310 reads (18%) | catalogued as COSV61752769; called by muse, mutect2, varscan2
- EIF2B5 | c.1329G>C p.V443= (on ENST00000647909; = p.V435= on NM_003907.3) | Splice Region (SNP) | VAF 41/203 reads (20%) | catalogued as COSV56603850; called by muse, mutect2, varscan2
- ELMOD3 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV55525006; called by muse, mutect2, varscan2
- ERMAP | c.1295C>G p.A432G | Missense Mutation (SNP) | VAF 144/665 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs375385333, COSV60273586; called by muse, mutect2, varscan2
- FAHD2B | c.751C>A p.Q251K | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs1183859136, COSV55630086; called by muse, mutect2, varscan2
- FCGR1A | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.114); catalogued as COSV100977263; called by muse, mutect2
- FRK | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as rs775194998, COSV101606630; called by muse, mutect2
- GBP6 | c.54T>G p.N18K | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV65010886; called by muse, mutect2, varscan2
- GMPS | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55808278; called by muse, mutect2, varscan2
- GPRC6A | c.2209C>A p.P737T | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV59951947; called by muse, mutect2, varscan2
- GSPT1 | c.8T>G p.L3R (on ENST00000420576 / NM_001130007.2; = p.L141R on NM_002094.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV70452482; called by muse, mutect2, varscan2
- H4C13 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV100137718; called by muse, mutect2
- HIVEP3 | c.3808A>G p.T1270A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99911637; called by mutect2, varscan2
- HMCN1 | c.8743G>C p.E2915Q | Missense Mutation (SNP) | VAF 33/642 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.644); catalogued as COSV99624892; called by muse, mutect2
- IARS1 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100986783; called by muse, mutect2
- IL16 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 168/207 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376544346, COSV57269242; called by muse, mutect2, varscan2
- IRF6 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV65418779; called by muse, mutect2, varscan2
- ITPR2 | c.1772C>G p.A591G | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV67265984; called by muse, mutect2, varscan2
- KCTD20 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV54802404; called by muse, mutect2, varscan2
- LNX1 | c.1544G>C p.G515A (on ENST00000263925 / NM_001126328.3; = p.G419A on NM_032622.2) | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV55782820; called by muse, mutect2, varscan2
- LYST | c.5927A>G p.Y1976C | Missense Mutation (SNP) | VAF 108/449 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV67704092; called by muse, mutect2, varscan2
- MAGEC2 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 210/555 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.262); catalogued as COSV55998249; called by muse, mutect2, varscan2
- MICAL2 | c.2554C>A p.Q852K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV99816806; called by muse, mutect2
- MRGPRX1 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57106174; called by muse, mutect2, varscan2
- MTRR | c.1732C>G p.P578A (on ENST00000264668; = p.P551A on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52942116, COSV52946781; called by muse, mutect2, varscan2
- MYBL2 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 17/417 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406041; called by muse, mutect2
- MYC | c.1093C>A p.Q365K (on ENST00000377970; = p.Q380K on NM_002467.6) | Missense Mutation (SNP) | VAF 110/1109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99419498; called by muse, mutect2
- MYO1B | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV58428165, COSV58431152; called by muse, mutect2, varscan2
- NDUFV1 | c.408C>G p.H136Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV59594860; called by muse, mutect2, varscan2
- NF1 | c.5188A>C p.T1730P (on ENST00000358273 / NM_001042492.3; = p.T1709P on NM_000267.3) | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM143430, COSV55985620; called by muse, mutect2, varscan2
- NGLY1 | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54984501; called by muse, mutect2, varscan2
- NLRC5 | c.3788T>G p.L1263R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52650453; called by muse, mutect2, varscan2
- NPAS4 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV60649164, COSV60653254; called by muse, mutect2, varscan2
- OR1A1 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 168/698 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV58403304; called by muse, mutect2, varscan2
- OR2M3 | c.328T>G p.S110A | Missense Mutation (SNP) | VAF 44/1154 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101513400; called by muse, mutect2
- OR8H1 | c.928T>A p.S310T | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV57293295; called by muse, mutect2, varscan2
- PARP4 | c.2852C>G p.T951R | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960847; called by muse, mutect2, varscan2
- PBRM1 | c.2889C>G p.Y963* | Nonsense Mutation (SNP) | VAF 60/313 reads (19%) | catalogued as COSV56264202, COSV56272944; called by muse, mutect2, varscan2
- PCDHGC3 | c.1516G>C p.V506L | Missense Mutation (SNP) | VAF 105/165 reads (64%) | SIFT tolerated (1); PolyPhen possibly damaging (0.621); catalogued as COSV52745493; called by muse, mutect2, varscan2
- PCSK2 | c.1433A>G p.K478R | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99358810; called by muse, mutect2
- PCSK9 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56160949; called by muse, mutect2, varscan2
- PDE4A | c.931C>G p.Q311E (on ENST00000380702 / NM_001111307.2; = p.Q72E on NM_006202.3) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.108); catalogued as rs1380029803, COSV53351513; called by muse, mutect2, varscan2
- PDE4D | c.1594G>C p.E532Q (on ENST00000340635 / NM_001104631.2; = p.E396Q on NM_006203.4) | Missense Mutation (SNP) | VAF 158/249 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57715554, COSV57721807; called by muse, mutect2, varscan2
- PFDN5 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs199718276, COSV54475184, COSV99229210; called by muse, mutect2, varscan2
- PFN4 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV57531064; called by muse, mutect2, varscan2
- PGM2L1 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV53345569; called by muse, mutect2, varscan2
- PI4KB | c.1196T>G p.I399S (on ENST00000368873 / NM_001369623.1; = p.I411S on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55015691; called by muse, mutect2, varscan2
- PLD1 | c.2098C>G p.R700G | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60565971, COSV60569980; called by muse, mutect2, varscan2
- PLSCR1 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 122/606 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV61012506; called by muse, mutect2, varscan2
- PLVAP | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV53083807; called by muse, mutect2, varscan2
- POLA1 | c.3175G>T p.V1059F | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV66884150; called by muse, mutect2, varscan2
- POLR2B | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.311); catalogued as rs768464675, COSV58898976; called by muse, mutect2, varscan2
- PRRC2A | c.2449G>C p.D817H | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV101051034; called by muse, mutect2
- PRSS53 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99762047; called by muse, mutect2
- PTPRT | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV61965308, COSV61997986; called by muse, mutect2, varscan2
- PUS3 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 109/416 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57102328; called by muse, mutect2, varscan2
- RAB37 | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61192827; called by muse, mutect2, varscan2
- RASA1 | c.2704C>G p.L902V | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57192197; called by muse, mutect2, varscan2
- RBM28 | c.1170G>C p.Q390H | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56161816; called by muse, mutect2, varscan2
- RCOR2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV56849558; called by muse, mutect2, varscan2
- RIPOR3 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99245982; called by muse, mutect2
- RMND5A | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV52152944; called by muse, mutect2, varscan2
- ROBO2 | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59900440, COSV59935638; called by muse, mutect2, varscan2
- RRP7A | c.666C>G p.S222R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV59899148; called by muse, mutect2
- SARDH | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV64098704; called by muse, mutect2, varscan2
- SBF1 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV62366170; called by muse, mutect2, varscan2
- SCIN | c.1996G>T p.E666* (on ENST00000297029 / NM_001112706.3; = p.E419* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV51690044; called by muse, mutect2, varscan2
- SETD7 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56799221, COSV99918367; called by muse, mutect2
- SHANK1 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53244877; called by muse, mutect2, varscan2
- SIDT1 | c.2160C>A p.N720K | Missense Mutation (SNP) | VAF 52/632 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99333231; called by muse, mutect2
- SIK3 | c.3209del p.S1071Vfs*11 (on ENST00000445177 / NM_001366686.2; = p.S1029Vfs*11 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as COSV99407862; called by mutect2, varscan2
- SLC10A6 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907173, COSV99907448; called by muse, mutect2, varscan2
- SLC10A6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775035778, COSV56722282; called by muse, mutect2, varscan2
- SLC11A1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.641); catalogued as COSV51916005; called by muse, mutect2, varscan2
- SLC26A5 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.557); catalogued as rs61997196, COSV100098724; called by muse, mutect2, varscan2
- SLC35A5 | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 34/421 reads (8%) | catalogued as rs1321268280, COSV99656711; called by muse, mutect2
- SLC38A4 | c.1385C>A p.A462E | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as COSV56965527; called by muse, mutect2, varscan2
- SLC38A7 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.484); catalogued as COSV54702467; called by muse, mutect2, varscan2
- SLC9C1 | c.831A>C p.L277F | Missense Mutation (SNP) | VAF 82/373 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59885895; called by muse, mutect2, varscan2
- SLC9C2 | c.851T>G p.L284R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62944285; called by muse, mutect2, varscan2
- SLIT1 | c.530T>G p.F177C | Missense Mutation (SNP) | VAF 59/461 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56584132; called by muse, mutect2, varscan2
- SNTA1 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV54128477; called by muse, mutect2, varscan2
- SPEF2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs368259023; called by muse, mutect2, varscan2
- STAG3 | c.2581C>G p.H861D | Missense Mutation (SNP) | VAF 12/456 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV100425669; called by muse, mutect2
- STARD4 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 90/144 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as COSV56967428; called by muse, mutect2, varscan2
- STX12 | c.824C>G p.T275R | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs758908219, COSV64248939, COSV64249039; called by muse, mutect2, varscan2
- SUPT6H | c.1580G>C p.C527S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs770086884, COSV58925169; called by muse, mutect2, varscan2
- TEKT4 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV54623347; called by muse, mutect2, varscan2
- TENM4 | c.6287C>G p.A2096G | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.985); catalogued as COSV53613121; called by muse, mutect2, varscan2
- TENT5B | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV56692535; called by muse, mutect2, varscan2
- TGFBR1 | c.650G>C p.G217A | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66625068; called by muse, mutect2, varscan2
- TMEM127 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV51497204; called by muse, mutect2, varscan2
- TRAK1 | c.2629C>A p.P877T | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59640053; called by muse, mutect2, varscan2
- TRIM59 | c.956A>T p.K319M | Missense Mutation (SNP) | VAF 49/578 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100557438; called by muse, mutect2
- TRPV4 | c.1274A>G p.D425G | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55680732; called by muse, mutect2, varscan2
- TSNAX | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs760939212, COSV64145771, COSV64147214; called by muse, mutect2
- TYW3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs544642809, COSV63802513; called by muse, mutect2, varscan2
- UBE3C | c.2010G>C p.L670F | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV61951825; called by muse, mutect2, varscan2
- USP2 | c.1502A>G p.H501R | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV52727867; called by muse, mutect2, varscan2
- VPS13A | c.9392A>T p.E3131V | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.661); catalogued as COSV64327077; called by muse, mutect2, varscan2
- ZBTB7B | c.536A>G p.D179G (on ENST00000292176; = p.D213G on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as COSV52691730; called by muse, mutect2, varscan2
- ZFAND4 | c.2032A>C p.S678R | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV60857967; called by muse, mutect2, varscan2
- ZNF169 | c.1548C>G p.D516E | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100566151; called by muse, mutect2
- ZNF644 | c.2953C>A p.H985N | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61346328; called by muse, mutect2, varscan2
- ZPLD1 | c.1129G>A p.G377R (on ENST00000466937 / NM_001329788.1; = p.G393R on NM_175056.2) | Missense Mutation (SNP) | VAF 86/598 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60352317; called by muse, mutect2, varscan2
- ZSWIM2 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54574184; called by muse, mutect2, varscan2
- ZSWIM8 | c.4778_4786del p.E1593_L1596delinsV (on ENST00000605216 / NM_001242487.2; = p.E1598_L1601delinsV on NM_015037.3) | In Frame Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV55213104; called by mutect2, pindel, varscan2
- ACACA | c.3565G>C p.V1189L | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACBD5 | c.964-22_969del p.X322_splice (on ENST00000375888 / NM_001352568.1; = p.X313_splice on NM_145698.5 and 4 other RefSeq transcripts) | Splice Site (DEL) | VAF 36/264 reads (14%) | called by mutect2, pindel
- ACER3 | c.741_750+14del p.X247_splice | Splice Site (DEL) | VAF 40/324 reads (12%) | called by mutect2, pindel
- APOB | c.318_329del p.N106_G109del | In Frame Del (DEL) | VAF 68/105 reads (65%) | called by mutect2, pindel, varscan2
- CENPE | c.6033_6079del p.L2011Ffs*3 | Frame Shift Del (DEL) | VAF 36/203 reads (18%) | called by mutect2, pindel
- COL1A1 | c.1008_1025del p.T337_P342del | In Frame Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, varscan2
- CREBBP | c.3911_3914+10del p.X1304_splice | Splice Site (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- CYTH4 | c.595_600del p.L199_H200del | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- DHRS11 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ITGAL | c.1339_1345del p.Q447Rfs*31 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- LAT | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAA25 | c.2699_2709del p.L900Cfs*6 | Frame Shift Del (DEL) | VAF 79/261 reads (30%) | called by mutect2, varscan2
- NOX5 | c.859_869del p.L287Tfs*106 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel
- NQO1 | c.108_122del p.E36_S40del | In Frame Del (DEL) | VAF 43/121 reads (36%) | called by mutect2, pindel, varscan2
- NTNG1 | c.247-3_265del p.X83_splice | Splice Site (DEL) | VAF 82/632 reads (13%) | called by mutect2, pindel
- PCNT | c.78_79insCAAA p.T27Qfs*5 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- SCAP | c.100_122+1del p.X34_splice | Splice Site (DEL) | VAF 26/270 reads (10%) | called by mutect2, pindel
- SLC19A2 | c.1412_1448del p.L471Qfs*12 | Frame Shift Del (DEL) | VAF 64/411 reads (16%) | called by mutect2, pindel*
- TBC1D14 | c.1336_1351+14del p.X446_splice | Splice Site (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel
- TMEM245 | c.1986_1994del p.F662_T665delinsL | In Frame Del (DEL) | VAF 40/260 reads (15%) | called by mutect2, pindel*, varscan2
- TTN | c.100583_100595del p.L33528Pfs*5 (on ENST00000591111; = p.L26104Pfs*5 on NM_003319.4) | Frame Shift Del (DEL) | VAF 257/721 reads (36%) | called by mutect2, pindel, varscan2
- ARHGEF2 | c.1194C>T p.I398= (on ENST00000361247 / NM_001162383.2; = p.I370= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV58107460; called by muse, mutect2, varscan2
- BCL9L | c.2082C>G p.P694= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV52682622; called by muse, mutect2, varscan2
- BOD1L1 | c.372A>G p.S124= | Silent (SNP) | VAF 57/309 reads (18%) | catalogued as rs1255837964, COSV50007566; called by muse, mutect2, varscan2
- CACNA1E | c.5208G>C p.L1736= | Silent (SNP) | VAF 38/356 reads (11%) | catalogued as COSV62384641; called by muse, mutect2
- CEP128 | c.2010A>G p.A670= | Silent (SNP) | VAF 88/321 reads (27%) | catalogued as COSV55370325; called by muse, mutect2, varscan2
- CNKSR1 | c.1774C>T p.L592= (on ENST00000374253 / NM_001297647.2; = p.L585= on NM_006314.3) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV58792455; called by muse, mutect2, varscan2
- CNTFR | c.309G>T p.L103= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV63633310; called by muse, mutect2, varscan2
- COG7 | c.972C>T p.F324= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs747262700, COSV56149361; ClinVar: likely benign; called by muse, mutect2, varscan2
- CWC25 | c.420C>T p.F140= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- CYP4B1 | c.114G>T p.T38= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs894906576, COSV54721666, COSV99597127; called by muse, mutect2, varscan2
- DDX42 | c.1729C>A p.R577= | Silent (SNP) | VAF 10/290 reads (3%) | catalogued as COSV100834841, COSV63789960; called by muse, mutect2
- FERD3L | c.246C>T p.R82= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs999975859, COSV51761945; called by muse, mutect2, varscan2
- FRY | c.1668C>T p.Y556= | Silent (SNP) | VAF 72/264 reads (27%) | catalogued as COSV66566324; called by muse, mutect2, varscan2
- GAS2L2 | c.1773C>A p.P591= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- GBP5 | c.981A>G p.Q327= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as COSV58591828; called by muse, mutect2, varscan2
- GNPAT | c.450C>T p.A150= | Silent (SNP) | VAF 22/270 reads (8%) | catalogued as COSV100791563; called by muse, mutect2
- H2BC11 | c.333C>G p.A111= | Silent (SNP) | VAF 61/211 reads (29%) | catalogued as rs751179949, COSV60361769; called by muse, mutect2, varscan2
- HERC2 | c.1905G>C p.G635= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as COSV55311487; called by muse, mutect2, varscan2
- HNF1A | c.1011C>T p.S337= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs549471872, COSV57459928; called by muse, mutect2, varscan2
- HPS4 | c.1497A>G p.E499= | Silent (SNP) | VAF 37/207 reads (18%) | catalogued as COSV61102719; called by muse, mutect2, varscan2
- HPX | c.138G>C p.V46= | Silent (SNP) | VAF 84/400 reads (21%) | catalogued as COSV56418702; called by muse, mutect2, varscan2
- IFT80 | c.1740G>A p.L580= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as COSV58445881; called by muse, mutect2, varscan2
- INPPL1 | c.2355C>G p.A785= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV53353785; called by muse, mutect2, varscan2
- JAK2 | c.3345C>T p.S1115= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV67586321; called by muse, mutect2, varscan2
- KCNQ3 | c.783C>G p.L261= | Silent (SNP) | VAF 59/510 reads (12%) | catalogued as COSV66465067; called by muse, mutect2, varscan2
- KPNA5 | c.1053A>C p.P351= | Silent (SNP) | VAF 125/175 reads (71%) | catalogued as COSV62651446; called by muse, mutect2, varscan2
- LRP1 | c.10317C>T p.C3439= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs1342752312, COSV54504032; called by muse, mutect2, varscan2
- LRRCC1 | c.2061T>G p.S687= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV64482797; called by muse, mutect2, varscan2
- MAGT1 | c.57C>G p.L19= (on ENST00000618282 / NM_001367916.1; = p.L51= on NM_032121.5) | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100800070; called by muse, mutect2, varscan2
- MAPK1 | c.471C>G p.L157= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as COSV53185327, COSV53185355; called by muse, mutect2, varscan2
- MUC17 | c.11460C>A p.L3820= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV60281971, COSV60302183; called by muse, mutect2, varscan2
- NOVA2 | c.1251G>A p.L417= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV54356222; called by muse, mutect2, varscan2
- NUP133 | c.1428G>A p.R476= | Silent (SNP) | VAF 160/385 reads (42%) | catalogued as rs1341904893, COSV54568855; called by muse, mutect2, varscan2
- OR52E8 | c.717A>T p.R239= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV66205191; called by muse, mutect2, varscan2
- OR5F1 | c.330C>T p.T110= | Silent (SNP) | VAF 87/299 reads (29%) | catalogued as rs573086848, COSV53545530, COSV99558547; called by muse, mutect2, varscan2
- OR8J3 | c.216C>T p.G72= | Silent (SNP) | VAF 136/339 reads (40%) | catalogued as rs936988530, COSV56879655; called by muse, mutect2, varscan2
- PCNX4 | c.2976T>A p.P992= (on ENST00000406854 / NM_001330177.2; = p.P758= on NM_022495.5) | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV58302691; called by muse, mutect2, varscan2
- PRKAA2 | c.510G>C p.L170= | Silent (SNP) | VAF 95/540 reads (18%) | catalogued as COSV64802390, COSV64806607; called by muse, mutect2, varscan2
- PROKR1 | c.915C>T p.I305= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs780436849, COSV58136811; called by muse, mutect2, varscan2
- PSMC4 | c.69C>T p.P23= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV99338143; called by muse, mutect2
- SEZ6L | c.1128C>T p.D376= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs371203903; called by muse, mutect2, varscan2
- SLC12A5 | c.2178C>T p.G726= (on ENST00000454036 / NM_001134771.2; = p.G703= on NM_020708.5) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1568866002, COSV54789748; called by muse, mutect2, varscan2
- SLC35F3 | c.111G>A p.A37= (on ENST00000366617 / NM_001300845.1; = p.A106= on NM_173508.4) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs752441220, COSV64018569; called by muse, varscan2
- STAM | c.1026C>T p.L342= | Silent (SNP) | VAF 108/322 reads (34%) | catalogued as rs782276274, COSV66324993; called by muse, mutect2, varscan2
- STOX2 | c.2034A>C p.G678= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as COSV57849448; called by muse, mutect2, varscan2
- TRAJ18 | c.60C>G p.V20= | Silent (SNP) | VAF 61/98 reads (62%) | called by muse, mutect2, varscan2
- TSPAN5 | c.465G>C p.G155= | Silent (SNP) | VAF 94/137 reads (69%) | catalogued as COSV59874325; called by muse, mutect2, varscan2
- USP54 | c.3354T>C p.Y1118= | Silent (SNP) | VAF 44/192 reads (23%) | catalogued as COSV60440348; called by muse, mutect2, varscan2
- VEPH1 | c.2373C>T p.F791= | Silent (SNP) | VAF 40/308 reads (13%) | catalogued as COSV62876648; called by muse, mutect2, varscan2
- WDR13 | c.1392C>T p.D464= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1370804923, COSV54330955; called by muse, mutect2, varscan2
- ZNF549 | c.1269G>T p.G423= (on ENST00000376233 / NM_001199295.2; = p.G410= on NM_153263.2) | Silent (SNP) | VAF 104/331 reads (31%) | catalogued as COSV53723950; called by muse, mutect2, varscan2
- DST | c.4297-2581G>A | Intron (SNP) | VAF 38/141 reads (27%) | catalogued as rs770236010, COSV55032947, COSV55046373; called by muse, mutect2, varscan2
- EPDR1 | c.-167C>T | 5'UTR (SNP) | VAF 14/26 reads (54%) | catalogued as COSV52258691; called by muse, mutect2, varscan2
- NIPAL2 | c.*1C>A | 3'UTR (SNP) | VAF 96/602 reads (16%) | catalogued as COSV100358267; called by muse, mutect2, varscan2
- PTK2 | c.1417+246C>A | Intron (SNP) | VAF 24/235 reads (10%) | catalogued as COSV61783130; called by muse, mutect2, varscan2
- SHOC1 | c.251-403G>C | Intron (SNP) | VAF 29/292 reads (10%) | catalogued as COSV100597322; called by muse, mutect2
- SSPOP | n.13408G>T | RNA (SNP) | VAF 7/16 reads (44%) | catalogued as COSV65127738; called by muse, mutect2, varscan2
- STARD7-AS1 | n.1612C>G | RNA (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
